TCGA case TCGA-UW-A7GR — Kidney Chromophobe (TCGA-KICH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a86c2490-37da-46a3-88e2-0b0ce21d067f

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 44 years; Vital status: Alive.

Diagnoses (2)
1. Renal cell carcinoma, chromophobe type (the primary disease): ICD-O-3 morphology code: 8317/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 44.4 years (16,221 days); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC clinical M: M1; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes; Days to last follow up: 3,109 days (8.5 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 1.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Interferon; Days to treatment start: 22 days; Days to treatment end: 288 days; Treatment outcome: Partial Response; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Sorafenib; Days to treatment start: 22 days; Days to treatment end: 288 days; Treatment outcome: Partial Response; Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the uterus (histology not recorded by GDC). Age at diagnosis: 44.2 years (16,152 days); Days to diagnosis: -69 days; FIGO stage: Stage I; FIGO staging edition year: 1988.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -69 days; Treatment anatomic sites: Cervix / Uterus.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 930 days (2.5 years); Disease response: Tumor Free.
- Days to follow up: 3,109 days (8.5 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking quit year: 2005.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UW-A7GR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide TCGA-UW-A7GR-01Z-00-DX1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 55; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-UW-A7GR-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UW-A7GR-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide TCGA-UW-A7GR-11Z-00-DX1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 60; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-UW-A7GR-11Z: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: Yes, Pharmaceutical Treatment Prior to Resection; Lymph nodes examined: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Uterus.
- Other malignancy form, Surgery: Other malignancy surgery type: TAH.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: systemic treatment.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,109 days; disease-specific survival: no event (censored), 3,109 days; progression-free interval: no event (censored), 3,109 days.
